Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A5UA, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A5UA-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report **(For Collection of Cancerous Tissue)**

ICD-O-3
path Carcinoma, papillary transitional cell 8130/3
C67F Carcinoma, Urothelial NOS 8120/3
Site C67F Bladder, NOS C67.9
path Bladder, overlapping lesion C67.8
JW 4/2/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
	1m70	☐ Single ☒ Married ☐ Divorced ☐ Widow		VIETNAMESE
Gender	Weight	Blood Pressure		Temperature
☒ Male ☐ Female	52 kg	12/7		37.5
		Heart Rate		78

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	weight loss, blood in urine
Symptoms:	weight loss, hematuria
Clinical Findings:	
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		one pack/day	30 (yrs)	3 months (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1/2 drink/day	20 (yrs)	3 months (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A Tumor in the bladder	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Urinary bladder cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T2 N0 M0 Stage: II	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of the tumor		
Primary Tumor		
Organ	Detailed Location	Size
Urinary bladder tumor	overlapping lesion	3 x 2 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T2 N0 M0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

Preserved by: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
urinary bladder tumor	3 x 2 x 2 cm	overlapping lesion	4 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT2 N0 M0 Stage: II			
Notes:			

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern									
Cell Distribution					Structural Pattern				
	+	-				+	-		
Diffuse		X	Streaming						
Mosaic	X		Storiform						
Necrosis		X	Fibrosis						
Lymphocytic Infiltration	X		Palsading						
Vascular Invasion		X	Cystic Degeneration						
Clusterized	X		Bleeding						
Alveolar Formation		X	Myxoid Change						
Indian File		X	Psammoma/Calcification						

Cellular Differentiation																
Squamous				Adenomatous				Sarcomatous				Lymphomatous				
	+	-				+	-		+	-		+	-			
Squamoid Cell	X		Glandular cell					Round Cell				Large Cell				
Spindle Cell	X		Cell Stratification					Fibroblast				Small Cell				
Keratin			Secretion					Osteoblast				RS Cell/RS Like				
Desmosome			Intracyt. Vacuole					Lipoblast				Inflam. Cell				
Pearl			Gland formation					Myoblast				Plasma Cell				

Cellular Differentiation: ☒ Well ☐ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism		X		
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity		X		

Nuclear Grade: ☒ 0 ☐ I ☐ II ☐ III

D1 70% D2 70% D3 40% D4 50%

Final Pathology Report

Histological Diagnosis: Papillary transitional cell carcinoma **Grade:** 1

Comments:

Director, Research Pathology

Date

Source: NCI Genomic Data Commons file bf7c1b84-c359-44a4-bbce-31eee758d2df (TCGA-CF-A5UA.6D1029C3-2277-488A-A02D-0048DBDFABE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).